Somatic mutation profile of tumor specimen 0DDIKP from CCDI case PBBNRK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.4 years (519 days).
Specimen 0DDIKP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac8addcc-d009-4801-aeed-c89b54501e48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDIK8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aa67d72-106b-4fbf-95bc-7470c8d9beab

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 7, Missense Mutation 6, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 104/288 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- KIF13A | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1252217511; called by muse, mutect2
- LTBP1 | c.4745C>T p.T1582M (on ENST00000404816 / NM_206943.4; = p.T1256M on NM_000627.4) | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs534680091, COSV55375405; called by muse, mutect2, varscan2
- NWD2 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1244255021; called by muse, mutect2
- PTCH1 | c.3488dup p.V1164Rfs*20 | Frame Shift Ins (INS) | VAF 309/453 reads (68%) | called by mutect2, pindel, varscan2
- ZFP82 | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- SLFN12L | c.1566C>T p.S522= (on ENST00000260908 / NM_001363830.1; = p.S540= on NM_001195790.1) | Silent (SNP) | VAF 173/397 reads (44%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, varscan2
- MKS1 | c.262-89T>C | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- MKS1 | c.262-90G>A | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as rs1289531751; called by muse, varscan2
- RC3H2 | c.3117+62G>A | Intron (SNP) | VAF 56/222 reads (25%) | called by muse, mutect2, varscan2
